Somatic mutation profile of tumor specimen TCGA-QG-A5YW-01A (aliquot TCGA-QG-A5YW-01A-11D-A28G-10) from TCGA case TCGA-QG-A5YW, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 55.8 years (20,391 days).
Specimen TCGA-QG-A5YW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a90acac-605d-47bb-82a4-9dc06fa81c76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QG-A5YW-10A (Blood Derived Normal), aliquot TCGA-QG-A5YW-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0766894f-a0a4-4c08-b406-6c1710d7e95d

The open-access MAF lists 167 somatic variants for this specimen: 121 protein-altering or splice-affecting, 34 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 34, Nonsense Mutation 11, 3'UTR 6, Splice Site 6, Frame Shift Del 3, Intron 2, RNA 2, Frame Shift Ins 1, In Frame Del 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.2945del p.N982Mfs*22 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs387906447, CD105308, COSV64273245; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 36/101 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.670C>T p.R224* (on ENST00000281708 / NM_001349798.2; = p.R144* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | hotspot (GDC flag); catalogued as rs1406877044, COSV55899023; called by muse, mutect2, varscan2
- FLNA | c.7255C>T p.R2419* (on ENST00000369850 / NM_001110556.2; = p.R2411* on NM_001456.3) | Nonsense Mutation (SNP) | VAF 50/177 reads (28%) | catalogued as rs782308324, CM1511674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 42/90 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.45A>C p.R15S | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs1064794096, CM114816, CX129932, COSV64290416, COSV64311104; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.994-1G>A p.X332_splice | Splice Site (SNP) | VAF 41/69 reads (59%) | hotspot (GDC flag); catalogued as rs587782272, CS002470, CS033842, CS103209, COSV52668116, COSV52746625, COSV52766192; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ADAMTS14 | c.3133G>T p.V1045L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1201527741; called by muse, mutect2, varscan2
- ADCY9 | c.2542G>A p.V848I | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs375674603; called by muse, mutect2, varscan2
- AMY2A | c.231C>A p.Y77* | Nonsense Mutation (SNP) | VAF 88/380 reads (23%) | catalogued as COSV70214532; called by muse, mutect2, varscan2
- ANKRD2 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV53968386; called by muse, mutect2, varscan2
- ATP2B3 | c.2485G>A p.D829N | Missense Mutation (SNP) | VAF 152/439 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141644369, COSV54848658; called by muse, mutect2, varscan2
- B2M | c.346+1G>C p.X116_splice | Splice Site (SNP) | VAF 37/60 reads (62%) | catalogued as COSV62563620, COSV62564969, COSV62566950; called by muse, mutect2, varscan2
- CALD1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775853439, COSV62647217; called by muse, mutect2, varscan2
- CARMIL1 | c.3244C>T p.R1082* | Nonsense Mutation (SNP) | VAF 25/146 reads (17%) | catalogued as rs1385108756, COSV61523112; called by muse, mutect2, varscan2
- CDC14A | c.368A>C p.N123T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1049104569, COSV60561465, COSV60562926; called by muse, mutect2, varscan2
- CEP162 | c.38T>G p.F13C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749447084; called by muse, mutect2, varscan2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2, varscan2
- CLCN4 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250705466; called by muse, mutect2, varscan2
- CSRNP3 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV58782351; called by muse, mutect2, varscan2
- CYP24A1 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs200955146; called by muse, mutect2, varscan2
- CYP2A13 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 96/282 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.395); catalogued as rs753958154, COSV100386917; called by muse, mutect2, varscan2
- DOCK1 | c.4499C>T p.T1500M | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs557337834; called by muse, mutect2, varscan2
- DROSHA | c.3453C>A p.D1151E | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60782483; called by muse, mutect2, varscan2
- EDNRA | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV100163580; called by muse, mutect2, varscan2
- EVX2 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs538737983, COSV57963043, COSV57963216; called by muse, mutect2
- F2 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as rs144785536, COSV61314992; called by muse, mutect2, varscan2
- F8 | c.6575-1G>A p.X2192_splice | Splice Site (SNP) | VAF 8/61 reads (13%) | catalogued as CS022494, COSV100371754; called by muse, mutect2, varscan2
- FAM124A | c.487C>T p.R163W (on ENST00000322475 / NM_001242312.2; = p.R199W on NM_145019.4) | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758162138, COSV54474974; called by muse, mutect2, varscan2
- FAM47C | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as rs1556332457, COSV63725336; called by muse, mutect2, varscan2
- FRMD7 | c.857C>A p.S286* | Nonsense Mutation (SNP) | VAF 36/95 reads (38%) | catalogued as COSV53746693; called by muse, mutect2, varscan2
- GAD2 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.2); catalogued as rs990840170, COSV52159671; called by muse, mutect2, varscan2
- GBP6 | c.1475G>T p.R492L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs933953523, COSV100969516; called by muse, varscan2
- GLE1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs779826538; called by muse, mutect2, varscan2
- GPR158 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV66265774; called by muse, mutect2, varscan2
- HMCN2 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs976742218; called by muse, mutect2, varscan2
- HNRNPK | c.1108+1G>A p.X370_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100699099; called by muse, mutect2, varscan2
- KCNA5 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV52905593; called by muse, mutect2, varscan2
- KIAA1549L | c.4450G>A p.E1484K (on ENST00000321505; = p.E1781K on NM_012194.3) | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58589578; called by muse, mutect2, varscan2
- KIAA2013 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 89/378 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs761268626; called by muse, mutect2, varscan2
- KLHL24 | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV54426478; called by muse, mutect2, varscan2
- LAMA5 | c.3914G>A p.G1305D | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV53360766; called by muse, mutect2, varscan2
- LCOR | c.4207G>T p.E1403* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV53714539; called by muse, mutect2, varscan2
- LRP1 | c.3860G>A p.G1287E | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.772); catalogued as COSV54517066; called by muse, mutect2, varscan2
- MAGEC1 | c.2807C>A p.T936K | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.598); catalogued as COSV53572675; called by muse, mutect2, varscan2
- MMP16 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs202054317, COSV54154850; called by muse, mutect2, varscan2
- MTCL1 | c.2684G>A p.R895H (on ENST00000306329 / NM_001378206.1; = p.R535H on NM_015210.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs767202575; called by mutect2, varscan2
- NES | c.2324T>C p.M775T | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as rs763450697; called by muse, mutect2, varscan2
- OR2B6 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 47/126 reads (37%) | catalogued as rs544975206; called by muse, mutect2, varscan2
- OTOP1 | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.113); catalogued as COSV56393502; called by muse, mutect2, varscan2
- PCMTD1 | c.706+1G>T p.X236_splice | Splice Site (SNP) | VAF 21/51 reads (41%) | catalogued as COSV62122582, COSV62125902; called by muse, mutect2, varscan2
- PIEZO2 | c.6619G>A p.G2207S | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200500089, COSV53287531; called by muse, mutect2, varscan2
- PRAMEF2 | c.336C>A p.F112L | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1201134321, COSV53574776, COSV53575838; called by muse, mutect2
- PSMD14 | c.511G>C p.G171R | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV68832583; called by muse, mutect2, varscan2
- PTPRS | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs146675930; called by muse, mutect2, varscan2
- QTRT2 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs867859440, COSV55560175; called by muse, mutect2, varscan2
- RAB26 | c.349-2A>T p.X117_splice | Splice Site (SNP) | VAF 84/190 reads (44%) | catalogued as COSV52954596; called by muse, mutect2, varscan2
- RAPGEF5 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.478); catalogued as rs570105930; called by muse, mutect2, varscan2
- RNF128 | c.347G>A p.W116* | Nonsense Mutation (SNP) | VAF 71/221 reads (32%) | catalogued as COSV55251295, COSV99718020; called by muse, mutect2, varscan2
- RP1L1 | c.4135G>T p.E1379* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as rs1255597183; called by muse, mutect2, varscan2
- SETD1B | c.3319G>A p.D1107N | Missense Mutation (SNP) | VAF 105/208 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.187); catalogued as rs1321839639, COSV57351310; called by muse, mutect2, varscan2
- SLC34A2 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs780836430; called by muse, mutect2, varscan2
- SLC46A2 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as rs1176941276; called by muse, mutect2
- SMAD2 | c.913C>G p.P305A | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51024023; called by muse, mutect2, varscan2
- SOAT1 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs770466169, COSV62654465; called by muse, mutect2, varscan2
- SORL1 | c.3475C>T p.R1159W | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs755000690, COSV52753838; called by muse, mutect2, varscan2
- TBX5 | c.1421C>G p.T474S | Missense Mutation (SNP) | VAF 64/112 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV59859176; called by muse, mutect2, varscan2
- TCHH | c.4729C>T p.R1577C | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV64272738; called by muse, mutect2, varscan2
- TCTE1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV65255466, COSV65256127; called by muse, mutect2, varscan2
- TTN | c.62569C>A p.Q20857K (on ENST00000591111; = p.Q13433K on NM_003319.4) | Missense Mutation (SNP) | VAF 59/93 reads (63%) | PolyPhen benign (0.005); catalogued as COSV100588714; called by muse, mutect2, varscan2
- TUBA3C | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 114/324 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.127); catalogued as rs1277948755, COSV67139269; called by muse, mutect2, varscan2
- UNK | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 214/252 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs201905047; called by muse, mutect2, varscan2
- USP26 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs756720175; called by muse, mutect2, varscan2
- ZFHX4 | c.8791C>T p.R2931C | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51484377; called by muse, mutect2, varscan2
- ZFHX4 | c.9899G>A p.G3300D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs757676087; called by muse, mutect2, varscan2
- ZNF449 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.877); catalogued as rs782132394; called by muse, mutect2, varscan2
- ABCA13 | c.14657G>T p.G4886V | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB11 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ACTR3B | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL2 | c.2615dup p.R873Pfs*6 (on ENST00000370717 / NM_001366005.1; = p.R860Pfs*6 on NM_012302.4) | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.15513G>T p.Q5171H | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMMECR1 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 108/266 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ATG4A | c.816T>C p.G272= | Splice Region (SNP) | VAF 76/245 reads (31%) | called by muse, mutect2, varscan2
- CACNG8 | c.691A>G p.S231G | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CAPN14 | c.1234C>G p.R412G | Missense Mutation (SNP) | VAF 80/144 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDH23 | c.7114G>T p.V2372L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- CLGN | c.474_476del p.L159del | In Frame Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- CNN2 | c.688A>G p.I230V | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL5A2 | c.740C>A p.P247Q | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT tolerated (0.75); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH5 | c.11575G>T p.V3859F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- DOCK11 | c.4819T>G p.L1607V | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- DSCAML1 | c.838G>A p.D280N (on ENST00000321322; = p.D220N on NM_020693.4) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EGFL8 | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- EPHA6 | c.721A>G p.K241E | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ERRFI1 | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- F8 | c.6221A>C p.Y2074S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- FBXL7 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FCN2 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HERC1 | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- KIAA0825 | c.3140A>C p.K1047T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- LAMA3 | c.8447T>C p.L2816P (on ENST00000313654 / NM_198129.4; = p.L1207P on NM_000227.6) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MAP2 | c.1963C>A p.P655T | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSD3 | c.3632A>G p.D1211G | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB15 | c.1345C>A p.P449T | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKG2 | c.1031A>G p.Q344R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- RNF123 | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCAF4 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 42/96 reads (44%) | called by muse, varscan2
- SEMA5A | c.1480A>T p.S494C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SEMA6A | c.1270G>C p.A424P | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- SIGLEC7 | c.897G>T p.Q299H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SLC5A9 | c.395C>A p.A132E | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SMURF2 | c.1836T>G p.H612Q | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STEAP1 | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- STT3A | c.1280C>G p.S427C | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SUN1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF5L | c.880del p.L294Ffs*9 | Frame Shift Del (DEL) | VAF 48/133 reads (36%) | called by mutect2, pindel, varscan2
- TRIO | c.4605C>A p.S1535R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- TRO | c.1746C>A p.D582E | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- VIPAS39 | c.804C>G p.D268E | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF367 | c.695G>A p.C232Y | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF562 | c.1086_1087del p.I363Tfs*12 (on ENST00000453372 / NM_001130032.2; = p.I291Tfs*12 on NM_017656.4) | Frame Shift Del (DEL) | VAF 42/136 reads (31%) | called by pindel, varscan2
- ACAD11 | c.555G>A p.K185= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs771473031; called by muse, mutect2, varscan2
- ADGRE2 | c.744C>T p.H248= | Silent (SNP) | VAF 72/788 reads (9%) | catalogued as rs776535410; called by muse, mutect2
- ADGRL1 | c.1053T>C p.N351= (on ENST00000340736 / NM_001008701.3; = p.N346= on NM_014921.5) | Silent (SNP) | VAF 19/252 reads (8%) | catalogued as COSV100529687; called by muse, mutect2
- AMIGO3 | c.1092G>A p.T364= | Silent (SNP) | VAF 58/135 reads (43%) | catalogued as rs769465616, COSV57539883; called by muse, mutect2, varscan2
- ASB15 | c.369G>A p.L123= | Silent (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- CNTN6 | c.1719A>G p.G573= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- COL1A1 | c.2166C>T p.G722= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs200188855, COSV99868335; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRIM1 | c.2703G>A p.L901= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- CUBN | c.5517C>T p.S1839= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs754868648, COSV64727422; called by muse, mutect2, varscan2
- DAO | c.264C>T p.G88= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV57322651; called by muse, mutect2, varscan2
- DYNC2H1 | c.9270T>A p.A3090= | Silent (SNP) | VAF 28/70 reads (40%) | called by muse, varscan2
- FER1L6 | c.3477C>T p.D1159= | Silent (SNP) | VAF 65/138 reads (47%) | catalogued as rs750405939; called by muse, mutect2, varscan2
- HSPA6 | c.870C>T p.F290= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as rs759271260, COSV59060583; called by muse, mutect2, varscan2
- IFRD1 | c.540G>T p.G180= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- INTS2 | c.1131G>A p.L377= | Silent (SNP) | VAF 163/202 reads (81%) | catalogued as rs1468512163, COSV52156767; called by muse, mutect2, varscan2
- KIR2DL1 | c.366C>A p.I122= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99383446; called by muse, mutect2, varscan2
- LRP1 | c.8967C>T p.T2989= | Silent (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2
- MAG | c.1296C>T p.C432= | Silent (SNP) | VAF 53/115 reads (46%) | catalogued as rs552648186, COSV62703094; called by muse, mutect2, varscan2
- MAN2B1 | c.2478G>A p.S826= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs958869615; called by muse, mutect2, varscan2
- MID1IP1 | c.213C>T p.P71= | Silent (SNP) | VAF 118/337 reads (35%) | called by muse, mutect2, varscan2
- NID1 | c.3594C>A p.I1198= | Silent (SNP) | VAF 43/118 reads (36%) | called by muse, mutect2, varscan2
- NPLOC4 | c.1233C>T p.Y411= | Silent (SNP) | VAF 90/166 reads (54%) | catalogued as rs368218835; called by muse, mutect2, varscan2
- PALD1 | c.807G>A p.L269= | Silent (SNP) | VAF 57/119 reads (48%) | called by muse, mutect2, varscan2
- PHLDB1 | c.2796C>T p.A932= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs782508605; called by muse, mutect2, varscan2
- QSOX1 | c.978C>T p.R326= | Silent (SNP) | VAF 57/129 reads (44%) | called by muse, mutect2, varscan2
- RAI1 | c.2550C>T p.F850= | Silent (SNP) | VAF 26/40 reads (65%) | catalogued as rs370245374; called by muse, mutect2, varscan2
- RHOBTB1 | c.624G>A p.L208= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs772792443; called by muse, mutect2, varscan2
- SH2D1A | c.144C>T p.H48= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs765804146; called by muse, mutect2, varscan2
- SHISA3 | c.102G>T p.V34= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs771746182; called by muse, mutect2, varscan2
- SNRPD2 | c.321C>T p.I107= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as rs759353268, COSV50003926; called by muse, mutect2, varscan2
- TECTA | c.4671C>T p.N1557= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs1223709038; called by muse, mutect2, varscan2
- TMEM185A | c.939G>A p.P313= | Silent (SNP) | VAF 103/466 reads (22%) | catalogued as rs1429270978; called by muse, mutect2, varscan2
- VAV1 | c.1218C>T p.D406= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as COSV58379995; called by muse, mutect2, varscan2
- VPS13B | c.5664C>T p.N1888= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as COSV62143366; called by muse, mutect2, varscan2
- A2M | c.4409-37A>G | Intron (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100588855; called by muse, mutect2, varscan2
- C14orf119 | c.*373A>C | 3'UTR (SNP) | VAF 48/142 reads (34%) | catalogued as COSV99400062; called by muse, mutect2, varscan2
- CCDC183 | c.270+10C>T | Intron (SNP) | VAF 45/107 reads (42%) | catalogued as rs1392790735; called by muse, mutect2, varscan2
- FUT9 | c.*4134C>A | 3'UTR (SNP) | VAF 26/59 reads (44%) | catalogued as COSV100133974; called by muse, mutect2, varscan2
- HMGN4 | c.*636A>C | 3'UTR (SNP) | VAF 24/74 reads (32%) | catalogued as COSV101110247; called by muse, mutect2, varscan2
- OR6A2 | c.-116C>A | 5'UTR (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100215786, COSV60265306; called by muse, mutect2
- P2RY10 | c.*262T>C | 3'UTR (SNP) | VAF 9/70 reads (13%) | catalogued as COSV99409247; called by muse, mutect2
- PABPC1L2B | c.*283C>A | 3'UTR (SNP) | VAF 66/363 reads (18%) | catalogued as COSV100999403; called by muse, mutect2, varscan2
- PDZD7 | chr10:101015782 C>A | 3'Flank (SNP) | VAF 29/137 reads (21%) | catalogued as COSV64646369; called by muse, mutect2, varscan2
- PIPSL | n.2622C>A | RNA (SNP) | VAF 39/186 reads (21%) | catalogued as rs1219083517; called by muse, mutect2, varscan2
- SIAH1P1 | n.33G>A | RNA (SNP) | VAF 63/163 reads (39%) | catalogued as rs938153947; called by muse, mutect2, varscan2
- ZBED6CL | c.*231G>A | 3'UTR (SNP) | VAF 9/28 reads (32%) | catalogued as rs1443684527, COSV100550586; called by muse, mutect2, varscan2
